TCGA case TCGA-E1-5304 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/691d5202-90cc-4e08-83a3-0620a89d3a4b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Dead; Days to death: 1,251 days (3.4 years).

Diagnoses (2)
1. Astrocytoma, anaplastic (the primary disease): ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 42.4 years (15,481 days); Year of diagnosis: 1999; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: >=181 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 69 days; Treatment dose: 5,940 cGy; Course number: 2; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 95 days; Days to treatment end: 125 days; Number of cycles: 1; Treatment dose: 1,500 mg; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 125 days; Days to treatment end: 160 days; Number of cycles: 1; Treatment dose: 2,000 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 160 days; Days to treatment end: 249 days; Number of cycles: 2; Treatment dose: 420 mg; Prescribed dose: 110; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 249 days; Days to treatment end: 312 days; Number of cycles: 2; Treatment dose: 3,950 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 312 days; Days to treatment end: 398 days (1.1 years); Number of cycles: 2; Treatment dose: 440 mg; Prescribed dose: 110; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 995 days (2.7 years); Days to treatment end: 1,113 days (3.0 years); Number of cycles: 4; Treatment dose: 7,700 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,128 days (3.1 years); Days to treatment end: 1,166 days (3.2 years); Number of cycles: 1; Treatment dose: 723 mg; Prescribed dose: 125; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 1,167 days (3.2 years); Days to treatment end: 1,198 days (3.3 years); Number of cycles: 1; Treatment dose: 2,100 mg; Prescribed dose: 50; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Recurrence of diagnosis 1 (Astrocytoma, anaplastic). Age at diagnosis: 44.9 years (16,384 days); Days to diagnosis: 903 days (2.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 980 days (2.7 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 160 (post adjuvant therapy): Karnofsky performance status: 90.
- Day 903 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 903 days (2.5 years).
- Days to follow up: 1,251 days (3.4 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Sensory Changes.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E1-5304-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.6.
  Slide TCGA-E1-5304-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-E1-5304-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-E1-5304-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: Yes; Symp changes motor movement: No; First symptom longest duration: > 181 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes; Family history brain tumor: No.
- Drug treatment 1: Regimen number: 3.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 6.
- Drug treatment 3: Regimen number: 7; Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 4: Regimen number: 8; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 9; Pharmaceutical therapy drug name: CPT-11; Therapy regimen: Progression.
- Drug treatment 5, Route of administrations: Route of administration: IV.
- Drug treatment 6: Regimen number: 5; Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 7: Regimen number: 10; Pharmaceutical therapy drug name: VP-16; Therapy regimen: Progression.
- Drug treatment 8: Regimen number: 4.
- Follow-up form: Treatment outcome first course: Stable Disease; New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: Yes; Performance status timing: Post-Adjuvant Therapy; Treatment outcome at TCGA followup: Stable Disease; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,251 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,251 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 903 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E1-5304-01A-01D-1466-01): tumor purity 0.93, ploidy 3.46, whole-genome doublings 1.
